TCGA case TCGA-IW-A3M5 — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Myomatous Neoplasms; Primary site: Uterus, NOS; Tissue source site: Cedars Sinai. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c20682a1-f340-430d-99f9-077fe093ed19

Demographics
Sex at birth: female; Race: white; Country of residence at enrollment: United States; Age at index: 76 years; Vital status: Dead; Days to death: 180 days.

Diagnoses (2)
1. Leiomyosarcoma, NOS (the primary disease): ICD-O-3 morphology code: 8890/3; ICD-10 code: C55; Tissue or organ of origin: Uterus, NOS; Site of resection or biopsy: Uterus, NOS; Classification of tumor: primary; Age at diagnosis: 76.3 years (27,869 days); Year of diagnosis: 2010; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Sites of involvement: Lung, NOS / Uterus; Tumor focality: Multifocal.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 3.5; Tumor length measurement: 5.5; Tumor width measurement: 5.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 0.3; Tumor length measurement: 1; Tumor width measurement: 0.7.
   Pathology details: Consistent pathology review: Yes; Margin status: Uninvolved; Necrosis percent: 9; Necrosis present: Yes.
2. Metastasis of diagnosis 1 (Leiomyosarcoma, NOS), site: Lung, NOS. Age at diagnosis: 76.3 years (27,878 days); Days to diagnosis: 9 days; Prior treatment: Yes.

Follow-up (3 entries)
- Day 0 (initial diagnosis): Discontiguous lesion count: 2.
- Day 9 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 9 days.
- Days to follow up: 180 days; Disease response: With Tumor.

Molecular and laboratory tests
- Test: Mitotic Count Reported; Mitotic count: 20.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-IW-A3M5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 160 mg.
  Slide TCGA-IW-A3M5-01A-02-TSB: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 5; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-IW-A3M5-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor.
- Primary pathology: Histologic diagnosis: Leiomyosarcoma (LMS); Histologic subtype: Poorly differentiated or pleomorphic or epithelioid leiomyosarcoma; Leiomyo major vessel involvement: No Major Vessel Involvement; Margin status: Negative; Tumor total necrosis: <10% (focal necrosis); Disease multifocal indicator: Yes; Discontinuous lesions count: 2; Locoregional recurrence indicator: No; Metastatic disease confirmed: Yes; Metastasis site: Lung; Contiguous organ invaded: No; Well diff liposarc prior diagnosis indicator: No.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Gynecological - Uterus.
- Primary pathology, Tumor sizes, Tumor size 1: Lesion pathologic width: 5.0.
- Primary pathology, Tumor sizes, Tumor size 2: Lesion pathologic length: 1.0.
- Follow-up form: Tumor status: With tumor; Treatment outcome at TCGA followup: Partial Response.
- Drug treatment 1: Regimen number: 1; Total dose: 3240000; Pharmaceutical treatment total dose units: mg; Prescribed dose: 675; Pharmaceutical treatment dose units: g/m2; Pharma adjuvant cycles count: 3; Days from index date to pharmaceutical treatment started: 147; Days from index date to pharmaceutical treatment ended: 170; Pharmaceutical therapy drug name: Gemcitabine; Therapy regimen: Adjuvant; Pharmaceutical treatment ongoing indicator: No.
- Drug treatment 1, Therapy types: Pharmaceutical therapy type: Chemotherapy.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Regimen number: 1; Total dose: 384000; Pharmaceutical treatment total dose units: mg; Prescribed dose: 80; Pharmaceutical treatment dose units: g/m2; Pharma adjuvant cycles count: 1; Days from index date to pharmaceutical treatment started: 154; Days from index date to pharmaceutical treatment ended: 154; Pharmaceutical therapy drug name: Docetaxel; Therapy regimen: Adjuvant; Pharmaceutical treatment ongoing indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 180 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 180 days; disease-free interval: event (new tumor event after initially disease-free), 9 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 9 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-IW-A3M5-01A-22D-A21P-01): tumor purity 0.86, ploidy 3.1, whole-genome doublings 1.
